Surgical pathology report (de-identified scan), TCGA case TCGA-34-5927, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-34-5927-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LUNG, RIGHT LOWER LOBE, LOBECTOMY -

- A. POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH NECROSIS (SEE COMMENT), 2.8 X 2.8 X 1.5 CM.
- B. NO DEFINITIVE LYMPHOVASCULAR INVASION IDENTIFIED.
- C. VASCULAR, BRONCHIAL (5.0CM) AND SOFT TISSUE (7.5CM) MARGINS OF RESECTION FREE OF TUMOR.
- D. THREE INTRALOBAR LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA WITH ANTHRACOSIS.
- E. TUMOR CONFINED IN LUNG PARENCHYMA, NO VISCERAL PLEURAL PENETRATION.
- F. NON TUMOR LUNG PARENCHYMA WITH FOCAL EMPHYSEMATOUS CHANGES, FOCAL CHRONIC INFLAMMATION AND HEMORRHAGE.
- G. AJCC PATHOLOGIC TNM STAGE: pT1 N0 MX.

PART 2: LUNG, RIGHT SECONDARY CARINA, BIOPSY - MINUTE AMORPHUS MATERIAL

PART 3: LYMPH NODE, LEVEL 8, BIOPSY -

ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA WITH ANTHRACOSIS.

PART 4: LYMPH NODE, LEVEL 9, BIOPSY -

ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA WITH ANTHRACOSIS.

PART 5: LYMPH NODE, SUPERIOR SEGMENT LEVEL 11, BIOPSY -

ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA WITH ANTHRACOSIS.

PART 6: LYMPH NODE, BASILAR LEVEL 11, BIOPSY -

ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA WITH ANTHRACOSIS.

PART 7: LYMPH NODE, LEVEL 10, BIOPSY -

ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA WITH ANTHRACOSIS.

PART 8: LYMPH NODE, LEVEL 4R, BIOPSY -

FRAGMENTS OF LYMPH NODES (MAXIMAL OF 3) NEGATIVE FOR METASTATIC CARCINOMA WITH ANTHRACOSIS.

PART 9: LYMPH NODE, LEVEL 7, BIOPSY -

FRAGMENTS OF LYMPH NODES (MAXIMAL OF 3) NEGATIVE FOR METASTATIC CARCINOMA WITH ANTHRACOSIS.

COMMENT:

The immunostains are as follows:

TTF-1	Negative
Cytokeratin 7	Positive
Cytokeratin 20	focally positive
P63	Positive
Cytokeratin 5/6	Positive

The morphology and immunostaining patterns support the squamous cell carcinoma. All control slides stained appropriately.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY LUNG TUMORS

TUMOR LOCATION:	Right Lower Lobe
PROCEDURE:	Lobectomy
TUMOR SIZE:	Maximum dimension: 2.8 cm
GROSS SATELLITES:	Number of gross satellite lesions: 0
TUMOR TYPE:	Invasive squamous carcinoma
HISTOLOGIC GRADE:	G3, Poorly differentiated
MICROSCOPIC SATELLITES:	Number of microscopic satellite lesions: 0
EXTRAPULMONARY PARENCHYMAL EXTENSION/INVASION OF TUMOR:	None identified
ANGIOLYMPHATIC INVASION:	No
TUMOR NECROSIS:	< or = 50%
SURGICAL MARGIN INVOLVEMENT:	No
SURGICAL MARGIN SITE:	Distance of invasive tumor to closest margin: 5.0 mm, Bronchial margin
INFLAMMATORY(DESMOPLASTIC) REACTION:	Moderate
N1 LYMPH NODES:	Number of N1 lymph nodes positive: 0 Number of N1 lymph nodes examined: 6
EXTRACAPSULAR SPREAD OF N1 METASTASES:	No
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 0 Number of N2 lymph nodes examined: 8
EXTRACAPSULAR SPREAD OF N2 METASTASES:	No
UNDERLYING DISEASE(S):	Emphysema
T STAGE, PATHOLOGIC:	pT1
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
ANCILLARY STUDIES:	Immunohistochemical stains

Source: NCI Genomic Data Commons file 4cdcb1db-61a8-437b-94dd-b11bb59e4a08 (TCGA-34-5927.581A7CC6-CEAB-4BA3-BAEC-FD675FD87732.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).